Somatic mutation profile of tumor specimen TCGA-IZ-A6M9-01A (aliquot TCGA-IZ-A6M9-01A-11D-A31X-10) from TCGA case TCGA-IZ-A6M9, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 63.4 years (23,149 days).
Specimen TCGA-IZ-A6M9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a8dcff9c-ff32-40fe-a5e4-7397bd56d9d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IZ-A6M9-10A (Blood Derived Normal), aliquot TCGA-IZ-A6M9-10A-01D-A31X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ae8ed7f-1dfc-40bb-8188-863d01c41c94

The open-access MAF lists 60 somatic variants for this specimen: 48 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 34, Silent 9, Frame Shift Del 8, In Frame Del 3, Nonsense Mutation 2, Intron 2, Splice Site 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADPRM | c.351T>G p.S117R | Missense Mutation (SNP) | VAF 79/145 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV65754334; called by muse, mutect2, varscan2
- CACNB1 | c.649-2A>T p.X217_splice | Splice Site (SNP) | VAF 49/80 reads (61%) | catalogued as COSV59997921; called by muse, mutect2, varscan2
- CEP135 | c.2471A>G p.Q824R | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs148279836; called by muse, mutect2, varscan2
- CEP135 | c.3113C>T p.A1038V | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.394); catalogued as rs370534878, COSV57257898; called by muse, mutect2, varscan2
- COL17A1 | c.3488A>C p.E1163A | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV62225073; called by muse, mutect2, varscan2
- CSMD3 | c.303T>G p.N101K | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.253); catalogued as COSV52094793, COSV52296447; called by muse, mutect2, varscan2
- DNAH8 | c.5293A>G p.I1765V | Missense Mutation (SNP) | VAF 52/105 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV59422883; called by muse, mutect2, varscan2
- DNAJC5G | c.167T>A p.L56Q | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56079426; called by muse, mutect2, varscan2
- ERBB2 | c.3209C>T p.A1070V | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as COSV54062619; called by muse, mutect2, varscan2
- EZR | c.1612C>G p.L538V | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV51907676; called by muse, mutect2, varscan2
- FAM193A | c.17T>A p.L6H | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61190632; called by muse, mutect2, varscan2
- FBXO34 | c.685T>A p.C229S | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV58253170; called by muse, mutect2, varscan2
- FBXO40 | c.2108C>T p.P703L | Missense Mutation (SNP) | VAF 46/54 reads (85%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as rs772415229, COSV57521711; called by muse, mutect2, varscan2
- FBXO5 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 31/82 reads (38%) | catalogued as COSV57670350; called by muse, mutect2, varscan2
- FGFRL1 | c.724A>C p.T242P | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV53256237; called by muse, varscan2
- GPR39 | c.1345C>A p.Q449K | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV61415676; called by muse, mutect2, varscan2
- GTF2IRD2 | c.1953C>G p.I651M | Missense Mutation (SNP) | VAF 53/288 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as COSV63100051; called by muse, mutect2, varscan2
- KDM5B | c.3975T>G p.Y1325* | Nonsense Mutation (SNP) | VAF 20/63 reads (32%) | catalogued as COSV52503676; called by muse, mutect2, varscan2
- LRRC14B | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV52043098; called by muse, mutect2
- MORC2 | c.283A>C p.T95P (on ENST00000397641 / NM_001303256.3; = p.T33P on NM_014941.3) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.969); catalogued as COSV53196017; called by muse, mutect2, varscan2
- MTFR1 | c.480A>C p.K160N | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV50951055; called by muse, mutect2, varscan2
- MYH4 | c.2304C>A p.F768L | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.603); catalogued as COSV55111657, COSV99701473; called by muse, mutect2, varscan2
- PDPR | c.605A>T p.N202I | Missense Mutation (SNP) | VAF 115/421 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.094); catalogued as COSV55348728; called by muse, mutect2, varscan2
- PEX16 | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs774416603, COSV53800675, COSV53803552; called by muse, mutect2, varscan2
- POTEE | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 72/204 reads (35%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.141); catalogued as rs1251130356, COSV58223535; called by muse, varscan2
- PRDM12 | c.793C>T p.H265Y | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1357885087, COSV53389516; called by muse, mutect2, varscan2
- PTPN14 | c.1661G>A p.S554N | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV65281258; called by muse, mutect2, varscan2
- RPRD2 | c.2342A>C p.E781A | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.177); catalogued as COSV64818522; called by muse, mutect2, varscan2
- SIGMAR1 | c.132G>C p.Q44H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.559); catalogued as COSV52844406; called by muse, mutect2, varscan2
- SLC25A5 | c.208T>G p.F70V | Missense Mutation (SNP) | VAF 44/69 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV58624482; called by muse, mutect2, varscan2
- SMPD1 | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs763512845, COSV54966157, COSV54969939; called by muse, mutect2, varscan2
- SULF1 | c.192C>G p.N64K | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV52672269; called by muse, mutect2, varscan2
- TCEAL4 | c.326A>T p.E109V | Missense Mutation (SNP) | VAF 98/116 reads (84%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.486); catalogued as COSV65463019; called by muse, mutect2, varscan2
- TMOD1 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52244548; called by muse, mutect2, varscan2
- TMTC4 | c.1417A>C p.S473R (on ENST00000376234 / NM_001350577.2; = p.S492R on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60891195; called by muse, mutect2, varscan2
- ZNF33B | c.1691A>G p.H564R | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.34); catalogued as rs1280679233, COSV63941760; called by muse, mutect2, varscan2
- ZNF407 | c.6211C>T p.R2071W | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1325541774, COSV55241794; called by muse, mutect2
- ARL6IP4 | c.634_638del p.S212Efs*56 (on ENST00000315580 / NM_018694.3; = p.S212Efs*37 on NM_016638.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 28/131 reads (21%) | called by mutect2, pindel, varscan2
- CNOT1 | c.2139_2143del p.L714Wfs*6 | Frame Shift Del (DEL) | VAF 43/93 reads (46%) | called by mutect2, pindel, varscan2
- DPYS | c.1487_1489del p.E496del | In Frame Del (DEL) | VAF 26/53 reads (49%) | called by mutect2, pindel, varscan2
- EIF2B2 | c.757_766del p.T253Wfs*84 | Frame Shift Del (DEL) | VAF 4/25 reads (16%) | called by mutect2, pindel, varscan2
- EPB41L1 | c.425_427del p.F142del | In Frame Del (DEL) | VAF 17/43 reads (40%) | called by mutect2, pindel, varscan2
- KIAA1614 | c.207_218del p.P70_W73del | In Frame Del (DEL) | VAF 20/55 reads (36%) | called by mutect2, pindel, varscan2
- LMO7 | c.2485_2503del p.K829Lfs*8 (on ENST00000357063; = p.K510Lfs*8 on NM_005358.5) | Frame Shift Del (DEL) | VAF 38/129 reads (29%) | called by mutect2, pindel, varscan2
- NKAPD1 | c.498del p.H166Qfs*14 (on ENST00000280352 / NM_001082970.2; = p.H167Qfs*14 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 71/221 reads (32%) | called by mutect2, pindel, varscan2
- NUFIP1 | c.243del p.F81Lfs*122 | Frame Shift Del (DEL) | VAF 19/90 reads (21%) | called by mutect2, pindel, varscan2
- VPS11 | c.1021del p.Q341Sfs*13 (on ENST00000620429; = p.Q885Sfs*13 on NM_021729.6 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 22/61 reads (36%) | called by mutect2, pindel, varscan2
- ZNF273 | c.1502_1510delinsAT p.L501Hfs*83 | Frame Shift Del (DEL) | VAF 12/68 reads (18%) | called by pindel, varscan2*
- AUTS2 | c.3642A>G p.T1214= | Silent (SNP) | VAF 29/101 reads (29%) | catalogued as COSV61381728; called by muse, mutect2, varscan2
- CLSTN1 | c.975C>T p.H325= (on ENST00000377298 / NM_001009566.3; = p.H315= on NM_014944.4) | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as rs771364918, COSV63646349; called by muse, mutect2, varscan2
- COL3A1 | c.2532C>T p.P844= | Silent (SNP) | VAF 25/75 reads (33%) | catalogued as COSV58581440; called by muse, mutect2, varscan2
- GDI2 | c.42G>T p.L14= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV101200801; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1428A>T p.P476= (on ENST00000485419 / NM_001197113.1; = p.P400= on NM_014575.3) | Silent (SNP) | VAF 60/78 reads (77%) | catalogued as COSV61838328; called by muse, mutect2, varscan2
- LNX1 | c.1743A>G p.T581= (on ENST00000263925 / NM_001126328.3; = p.T485= on NM_032622.2) | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs151307935, COSV55781710; called by muse, mutect2, varscan2
- MARCHF2 | c.588C>T p.S196= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV53104023; called by muse, mutect2, varscan2
- NEB | c.17031C>T p.V5677= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as rs1468263173, COSV50806680, COSV50916691; called by muse, mutect2, varscan2
- SUPT6H | c.3003G>T p.L1001= | Silent (SNP) | VAF 9/42 reads (21%) | catalogued as COSV58924322; called by muse, mutect2, varscan2
- CD300LD | chr17:74592423 G>T | 5'Flank (SNP) | VAF 17/62 reads (27%) | called by muse, mutect2, varscan2
- KARS1 | c.63-2679T>A | Intron (SNP) | VAF 53/94 reads (56%) | catalogued as COSV100094449; called by muse, mutect2, varscan2
- NOP56 | c.569+167G>A | Intron (SNP) | VAF 9/22 reads (41%) | catalogued as COSV100250298, COSV100250330; called by muse, mutect2, varscan2
